Somatic mutation profile of tumor specimen TCGA-43-A474-01A (aliquot TCGA-43-A474-01A-11D-A24D-08) from TCGA case TCGA-43-A474, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 66.5 years (24,286 days).
Specimen TCGA-43-A474-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e55e3eba-2181-4230-bc39-b64c484e15b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-43-A474-10A (Blood Derived Normal), aliquot TCGA-43-A474-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2b665386-8b2d-4999-b125-bf00ca5bcf8e

The open-access MAF lists 421 somatic variants for this specimen: 302 protein-altering or splice-affecting, 110 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 262, Silent 110, Nonsense Mutation 24, Splice Site 6, Frame Shift Del 5, Intron 4, Splice Region 4, RNA 3, 5'UTR 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NSD1 | c.7690G>T p.E2564* | Nonsense Mutation (SNP) | VAF 36/52 reads (69%) | catalogued as rs749416834, COSV100729732; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TPO | c.2077C>T p.R693W | Missense Mutation (SNP) | VAF 31/49 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs121908087, CM002645, COSV100221850, COSV61106041; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.1430A>T p.K477I | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV99286658; called by muse, mutect2, varscan2
- ABCA9 | c.1558G>T p.G520* | Nonsense Mutation (SNP) | VAF 15/78 reads (19%) | catalogued as COSV100383398; called by muse, mutect2, varscan2
- ACSM3 | c.466C>G p.Q156E | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV99184873; called by muse, mutect2, varscan2
- ACTN2 | c.2662C>A p.L888I | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.956); catalogued as COSV100856947; called by muse, mutect2, varscan2
- ADAMTS13 | c.4113C>A p.F1371L | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99390426; called by muse, mutect2
- ADAMTS18 | c.3023G>T p.G1008V | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99273879; called by muse, mutect2, varscan2
- ADAMTS19 | c.2506G>T p.A836S | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as COSV50772159, COSV99180119; called by muse, mutect2, varscan2
- ADAMTS9 | c.1743A>T p.E581D | Missense Mutation (SNP) | VAF 45/68 reads (66%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV99900049, COSV99900106; called by muse, mutect2, varscan2
- ADGRL1 | c.3313C>T p.H1105Y (on ENST00000340736 / NM_001008701.3; = p.H1100Y on NM_014921.5) | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV100529754; called by muse, mutect2, varscan2
- ADGRL3 | c.1203G>T p.E401D (on ENST00000506720 / NM_001322402.2; = p.E333D on NM_015236.6) | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101547357; called by muse, mutect2, varscan2
- AHNAK2 | c.12565G>A p.D4189N | Missense Mutation (SNP) | VAF 64/326 reads (20%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.998); catalogued as rs371196106; called by muse, mutect2, varscan2
- AKAP11 | c.4189C>T p.P1397S | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.028); catalogued as COSV99214247; called by muse, mutect2, varscan2
- AKAP13 | c.6730G>T p.A2244S (on ENST00000394518 / NM_007200.5; = p.A2248S on NM_006738.6) | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.134); catalogued as COSV100774383; called by muse, mutect2, varscan2
- ALOX15 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.087); catalogued as rs752703451, COSV53400863; called by muse, mutect2, varscan2
- AMTN | c.83C>G p.P28R | Missense Mutation (SNP) | VAF 46/193 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV100219831; called by muse, mutect2, varscan2
- ANKRD50 | c.1989G>T p.L663F | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101539029; called by muse, mutect2, varscan2
- APOBEC3H | c.52C>T p.R18C | Missense Mutation (SNP) | VAF 61/131 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100818867; called by muse, mutect2, varscan2
- ARID5B | c.611A>T p.D204V | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99690283; called by muse, mutect2, varscan2
- ARMC3 | c.931C>T p.L311F | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV99958714; called by muse, mutect2
- ARSK | c.1196A>T p.H399L | Missense Mutation (SNP) | VAF 66/110 reads (60%) | SIFT tolerated (0.07); PolyPhen benign (0.053); catalogued as COSV101187565; called by muse, mutect2, varscan2
- ASB8 | c.42C>A p.S14R | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV100480725; called by muse, mutect2, varscan2
- ASXL3 | c.3667G>T p.E1223* | Nonsense Mutation (SNP) | VAF 5/52 reads (10%) | catalogued as COSV99326156; called by muse, mutect2, varscan2
- ATG4D | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.953); catalogued as rs774622329, COSV57263644; called by muse, mutect2, varscan2
- ATP9A | c.2025G>T p.M675I | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100125507; called by muse, mutect2, varscan2
- ATRX | c.4011A>T p.R1337S | Missense Mutation (SNP) | VAF 30/37 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100971298; called by muse, mutect2, varscan2
- BAZ1A | c.1156C>T p.R386* | Nonsense Mutation (SNP) | VAF 26/72 reads (36%) | catalogued as COSV100701205; called by muse, mutect2, varscan2
- BIN1 | c.157A>C p.K53Q | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.978); catalogued as COSV99388419; called by muse, mutect2, varscan2
- BMP2 | c.643C>T p.R215W | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV101122081; called by muse, mutect2, varscan2
- BTN2A2 | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773988420, COSV100760579; called by muse, mutect2, varscan2
- C1GALT1 | c.581T>G p.F194C | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99777631; called by muse, mutect2, varscan2
- C7 | c.1339G>T p.E447* | Nonsense Mutation (SNP) | VAF 52/74 reads (70%) | catalogued as COSV100496447; called by muse, mutect2, varscan2
- C7orf31 | c.485C>A p.T162N | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.714); catalogued as COSV99384114; called by muse, varscan2
- CACNG5 | c.783G>T p.L261F | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.137); catalogued as COSV99400784; called by muse, mutect2, varscan2
- CAND1 | c.269C>T p.T90I | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.198); catalogued as COSV101598286; called by muse, mutect2, varscan2
- CAPN6 | c.1423C>T p.Q475* | Nonsense Mutation (SNP) | VAF 20/31 reads (65%) | catalogued as COSV100137030; called by muse, mutect2, varscan2
- CATSPERB | c.1515G>C p.K505N | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99831642; called by muse, mutect2, varscan2
- CCDC63 | c.1328T>A p.L443H | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100370571, COSV57531272; called by muse, mutect2, varscan2
- CD300LB | c.205C>A p.Q69K | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV100075553; called by muse, mutect2, varscan2
- CDH10 | c.788A>G p.N263S | Missense Mutation (SNP) | VAF 95/109 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100052755; called by muse, varscan2
- CDH18 | c.331C>G p.H111D | Missense Mutation (SNP) | VAF 111/144 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56904415, COSV99937016, COSV99937597; called by muse, mutect2, varscan2
- CDK5RAP2 | c.3463G>T p.D1155Y | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100575701; called by muse, mutect2, varscan2
- CEP350 | c.7307G>C p.S2436T | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as COSV100855107; called by muse, mutect2, varscan2
- CFH | c.757G>T p.E253* | Nonsense Mutation (SNP) | VAF 15/74 reads (20%) | catalogued as COSV100661600; called by muse, mutect2, varscan2
- CHAT | c.388-1G>T p.X130_splice | Splice Site (SNP) | VAF 14/28 reads (50%) | catalogued as COSV100340743; called by muse, mutect2, varscan2
- CHD9 | c.4553G>T p.R1518L | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99529616; called by muse, mutect2, varscan2
- CLTCL1 | c.4230C>G p.F1410L | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99595714; called by muse, mutect2, varscan2
- CMYA5 | c.8165C>A p.T2722N | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as COSV101484298; called by muse, mutect2, varscan2
- CNTNAP4 | c.772C>A p.L258M | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.436); catalogued as COSV100272884; called by muse, varscan2
- COG2 | c.73G>C p.E25Q | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.27); catalogued as COSV100794783, COSV64186278; called by muse, mutect2, varscan2
- COL12A1 | c.4057A>T p.T1353S | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0.015); catalogued as COSV100486364, COSV59403690; called by muse, mutect2, varscan2
- CPAMD8 | c.1900-1G>A p.X634_splice (on ENST00000651564; = p.X587_splice on NM_015692.5) | Splice Site (SNP) | VAF 5/25 reads (20%) | catalogued as COSV52237781; called by muse, mutect2, varscan2
- CRP | c.223A>G p.K75E | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV99660711; called by muse, mutect2, varscan2
- CRP | c.125C>A p.A42E | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.761); catalogued as rs765949437, COSV99660712; called by muse, mutect2, varscan2
- CRYBB1 | c.466G>T p.G156W | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.985); catalogued as COSV99316175; called by muse, mutect2, varscan2
- CSMD3 | c.2281C>G p.L761V (on ENST00000297405 / NM_001363185.1; = p.L657V on NM_052900.3) | Missense Mutation (SNP) | VAF 85/139 reads (61%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV52129362, COSV99828094, COSV99841759; called by muse, mutect2, varscan2
- CTNND2 | c.1181G>T p.G394V | Missense Mutation (SNP) | VAF 78/95 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV100480187; called by muse, mutect2, varscan2
- CUL3 | c.2096G>T p.R699I | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100024623; called by muse, mutect2, varscan2
- DCAF1 | c.3736G>A p.V1246I | Missense Mutation (SNP) | VAF 37/57 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV100244846; called by muse, mutect2, varscan2
- DCAF4L2 | c.637G>T p.V213L | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as rs748067917, COSV100151225, COSV60479829; called by muse, mutect2, varscan2
- DCDC1 | c.4759C>A p.R1587= (on ENST00000597505 / NM_001367979.1; = p.R694= on NM_020869.3) | Splice Region (SNP) | VAF 15/73 reads (21%) | catalogued as COSV100360747; called by muse, mutect2, varscan2
- DCDC1 | c.837G>C p.K279N | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100664052; called by muse, mutect2, varscan2
- DCUN1D4 | c.135A>G p.T45= | Splice Region (SNP) | VAF 14/46 reads (30%) | catalogued as COSV100584662; called by muse, mutect2, varscan2
- DCUN1D5 | c.450+1G>C p.X150_splice | Splice Site (SNP) | VAF 17/35 reads (49%) | catalogued as COSV99499234; called by muse, mutect2, varscan2
- DDR2 | c.2371C>A p.Q791K | Missense Mutation (SNP) | VAF 59/168 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0.158); catalogued as COSV100906808; called by muse, mutect2, varscan2
- DDX21 | c.426A>T p.E142D | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100826543; called by muse, mutect2, varscan2
- DIP2A | c.2786T>C p.M929T | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV100596249; called by muse, mutect2, varscan2
- DIS3L2 | c.2576G>T p.R859L | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV99807106; called by muse, mutect2, varscan2
- DMD | c.8862G>C p.E2954D | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100628851; called by muse, mutect2, varscan2
- DNAH5 | c.6080C>A p.S2027Y | Missense Mutation (SNP) | VAF 45/56 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99453131; called by muse, mutect2, varscan2
- DTWD1 | c.813A>C p.R271S | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV99233751; called by muse, mutect2, varscan2
- DVL1 | c.481G>C p.G161R | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV101127628; called by muse, mutect2, varscan2
- ECPAS | c.2434G>T p.G812C | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99399091; called by muse, mutect2, varscan2
- EMILIN2 | c.1207G>A p.G403S | Missense Mutation (SNP) | VAF 46/65 reads (71%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as rs745691687, COSV99598824; called by muse, mutect2, varscan2
- ERICH3 | c.2259C>G p.I753M | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.145); catalogued as COSV100445385; called by muse, mutect2, varscan2
- ESAM | c.410C>G p.S137C | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.556); catalogued as COSV99632070; called by muse, mutect2, varscan2
- ETAA1 | c.957G>T p.L319F | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.13); catalogued as COSV55473922, COSV99712906; called by muse, mutect2, varscan2
- EXOC2 | c.1247C>G p.S416* | Nonsense Mutation (SNP) | VAF 24/53 reads (45%) | catalogued as COSV100034096, COSV57863628; called by muse, mutect2, varscan2
- FAM135B | c.995C>A p.T332N | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV99426708; called by muse, mutect2, varscan2
- FAM90A1 | c.1207C>T p.R403C | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs1308065485, COSV56714674; called by muse, mutect2, varscan2
- FAT1 | c.1956T>G p.N652K | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.276); catalogued as COSV101499593; called by muse, mutect2, varscan2
- FBXO34 | c.1202A>G p.N401S | Missense Mutation (SNP) | VAF 72/148 reads (49%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as COSV100572132; called by muse, mutect2, varscan2
- FCGBP | c.964G>T p.A322S | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.079); catalogued as rs146119620; called by muse, mutect2, varscan2
- FLT3 | c.2464G>A p.G822R | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs148480385, COSV54054760; called by muse, mutect2, varscan2
- FMN2 | c.4963G>A p.E1655K | Missense Mutation (SNP) | VAF 59/161 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV60418414; called by muse, mutect2, varscan2
- FOXM1 | c.2233G>A p.E745K | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as rs754849672, COSV100700898; called by muse, mutect2, varscan2
- FREM2 | c.3327G>C p.Q1109H | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); catalogued as COSV99750375; called by muse, mutect2, varscan2
- FSTL5 | c.1168A>G p.T390A | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.212); catalogued as COSV100059968; called by muse, mutect2, varscan2
- GALNT17 | c.953T>G p.L318R | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); catalogued as COSV100355666; called by muse, mutect2, varscan2
- GATA3 | c.1321G>A p.A441T | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.32); catalogued as COSV60520182, COSV60520365; called by muse, mutect2, varscan2
- GATAD2B | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 62/168 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as COSV100897989; called by muse, mutect2, varscan2
- GDE1 | c.777G>C p.W259C | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62060025; called by muse, mutect2, varscan2
- GET3 | c.841G>A p.V281I | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.065); catalogued as rs1194330086, COSV62002446; called by muse, mutect2, varscan2
- GLB1L2 | c.1036G>T p.A346S | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100335467; called by muse, mutect2, varscan2
- GLB1L2 | c.1596-1G>T p.X532_splice | Splice Site (SNP) | VAF 31/92 reads (34%) | catalogued as COSV100335468; called by muse, mutect2, varscan2
- GNAT3 | c.598G>C p.D200H | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101242416; called by muse, mutect2, varscan2
- GOLGA5 | c.1867G>A p.E623K | Missense Mutation (SNP) | VAF 68/202 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs773720304, COSV50832528; called by muse, varscan2
- GOLM2 | c.481G>T p.E161* | Nonsense Mutation (SNP) | VAF 18/44 reads (41%) | catalogued as COSV100248023; called by muse, mutect2, varscan2
- GPAT3 | c.1128A>C p.E376D | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as COSV100023237; called by muse, mutect2, varscan2
- GPBP1 | c.256C>A p.H86N | Missense Mutation (SNP) | VAF 31/46 reads (67%) | SIFT deleterious (0.03); PolyPhen benign (0.311); catalogued as COSV99303058; called by muse, mutect2, varscan2
- GPRIN3 | c.1089C>G p.H363Q | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.019); catalogued as COSV100310949; called by muse, mutect2, varscan2
- GZMK | c.722G>T p.G241V | Missense Mutation (SNP) | VAF 41/57 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99140975; called by muse, mutect2, varscan2
- H4C9 | c.186C>A p.F62L | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV100574929; called by muse, mutect2, varscan2
- HECW2 | c.1789G>C p.E597Q | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.188); catalogued as COSV99648508; called by muse, mutect2, varscan2
- HEPH | c.440G>T p.G147V (on ENST00000343002; = p.G201V on NM_138737.5) | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV100295534; called by muse, mutect2, varscan2
- HEPHL1 | c.3401C>A p.S1134Y | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.034); catalogued as COSV100244267, COSV59889776, COSV59895075; called by muse, mutect2, varscan2
- HNMT | c.517G>T p.V173L | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.123); catalogued as COSV99699068; called by muse, mutect2, varscan2
- HPS6 | c.1823C>T p.A608V | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1399741422, COSV100154973; called by muse, mutect2, varscan2
- IDUA | c.1906G>T p.V636L | Missense Mutation (SNP) | VAF 40/59 reads (68%) | SIFT tolerated (0.1); PolyPhen benign (0.038); catalogued as COSV56104867, COSV99926359; called by muse, mutect2, varscan2
- IKZF2 | c.367G>T p.G123W | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100563797; called by muse, mutect2, varscan2
- IL1RAPL2 | c.605A>T p.Q202L | Missense Mutation (SNP) | VAF 34/39 reads (87%) | SIFT tolerated (0.6); PolyPhen benign (0.353); catalogued as COSV100781852; called by muse, mutect2, varscan2
- INTS1 | c.6004C>A p.L2002I | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.669); catalogued as COSV101248256; called by muse, mutect2, varscan2
- IRX1 | c.784G>T p.A262S | Missense Mutation (SNP) | VAF 47/60 reads (78%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as COSV57361180; called by muse, mutect2, varscan2
- ITGA7 | c.1247G>A p.R416Q (on ENST00000555728; = p.R372Q on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as rs1397229961, COSV57692605, COSV99151582; called by muse, mutect2, varscan2
- KAT6B | c.1633G>T p.D545Y | Missense Mutation (SNP) | VAF 38/58 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99768840; called by muse, mutect2, varscan2
- KCNH8 | c.1574A>C p.E525A | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.762); catalogued as COSV100110863; called by muse, mutect2, varscan2
- KCNQ3 | c.2219C>G p.T740R | Missense Mutation (SNP) | VAF 32/48 reads (67%) | SIFT tolerated (0.33); PolyPhen benign (0.084); catalogued as rs764065145, COSV101196343, COSV66478201; called by muse, mutect2, varscan2
- KDM6A | c.3634C>T p.Q1212* | Nonsense Mutation (SNP) | VAF 28/34 reads (82%) | catalogued as COSV65037414; called by muse, mutect2, varscan2
- KIAA0319L | c.595A>G p.I199V | Missense Mutation (SNP) | VAF 66/97 reads (68%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1358606760, COSV100357635; called by muse, mutect2, varscan2
- KIF21B | c.4129C>T p.R1377W (on ENST00000422435 / NM_001252100.2; = p.R1364W on NM_017596.4) | Missense Mutation (SNP) | VAF 70/190 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1217111451, COSV100145013; called by muse, mutect2, varscan2
- KLHL4 | c.1964C>T p.P655L | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100910103; called by muse, mutect2, varscan2
- KPNA2 | c.853C>T p.R285* | Nonsense Mutation (SNP) | VAF 109/279 reads (39%) | catalogued as rs1266467492, COSV57857239; called by muse, mutect2, varscan2
- KRTAP6-2 | c.140G>C p.R47P | Missense Mutation (SNP) | VAF 27/45 reads (60%) | PolyPhen benign (0.015); catalogued as rs79633020, COSV100588942; called by muse, mutect2, varscan2
- LENG8 | c.883G>C p.E295Q | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV100458042; called by muse, mutect2, varscan2
- LGR5 | c.307A>G p.T103A | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.145); catalogued as COSV99878333; called by muse, mutect2, varscan2
- LRP1B | c.4182G>C p.W1394C | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101252966; called by muse, mutect2
- LTBP1 | c.4560T>A p.D1520E (on ENST00000404816 / NM_206943.4; = p.D1194E on NM_000627.4) | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as rs892605296, COSV99698671; called by muse, mutect2, varscan2
- M1AP | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.127); catalogued as COSV99304451; called by muse, mutect2, varscan2
- MAGEB18 | c.981G>A p.M327I | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100305594; called by muse, mutect2, varscan2
- MAGEC1 | c.2981T>C p.M994T | Missense Mutation (SNP) | VAF 71/101 reads (70%) | SIFT deleterious (0.02); PolyPhen benign (0.08); catalogued as COSV99596336; called by muse, mutect2, varscan2
- MAP2K7 | c.1189G>A p.V397I | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV101209123; called by muse, mutect2, varscan2
- MDGA2 | c.1757C>A p.T586N (on ENST00000399232 / NM_001113498.2; = p.T288N on NM_182830.4) | Missense Mutation (SNP) | VAF 58/159 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100638109; called by muse, mutect2, varscan2
- MICAL2 | c.5329G>A p.E1777K | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.468); catalogued as COSV56284800; called by muse, mutect2, varscan2
- MRGPRX3 | c.122C>G p.A41G | Missense Mutation (SNP) | VAF 72/188 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs149836029, COSV66934013; called by muse, mutect2, varscan2
- MRPL1 | c.655C>A p.P219T | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100214010; called by muse, mutect2
- MS4A10 | c.432G>T p.K144N | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs751033872, COSV100382405; called by muse, mutect2, varscan2
- MTRR | c.1687C>G p.P563A (on ENST00000264668; = p.P536A on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/234 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.293); catalogued as COSV99242006; called by muse, mutect2, varscan2
- MXRA5 | c.7352C>A p.T2451N | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.956); catalogued as COSV99478801; called by muse, mutect2, varscan2
- MYCT1 | c.284G>C p.R95P | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV100924088, COSV65890890; called by muse, mutect2, varscan2
- MYH1 | c.3358G>T p.E1120* | Nonsense Mutation (SNP) | VAF 35/64 reads (55%) | catalogued as COSV99876683; called by muse, mutect2, varscan2
- NAV3 | c.939T>A p.S313R | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as COSV99894544; called by muse, mutect2, varscan2
- NECTIN1 | c.1348G>C p.E450Q | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.071); catalogued as rs769256224, COSV99872549; called by muse, mutect2, varscan2
- NEK9 | c.878C>A p.P293H | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99464449; called by muse, mutect2, varscan2
- NLRP13 | c.1009C>T p.Q337* | Nonsense Mutation (SNP) | VAF 17/78 reads (22%) | catalogued as COSV100738442; called by muse, mutect2, varscan2
- NLRP5 | c.1149G>C p.E383D | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT tolerated (0.32); PolyPhen benign (0.05); catalogued as COSV101173851; called by muse, mutect2, varscan2
- NUP62CL | c.523G>A p.V175M | Missense Mutation (SNP) | VAF 127/196 reads (65%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.006); catalogued as COSV100991064; called by muse, mutect2, varscan2
- NYAP1 | c.1235C>A p.P412H | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100278650; called by muse, mutect2, varscan2
- OBSCN | c.2493C>A p.Y831* | Nonsense Mutation (SNP) | VAF 25/88 reads (28%) | catalogued as COSV99483117; called by muse, mutect2, varscan2
- OFD1 | c.1182G>T p.E394D | Missense Mutation (SNP) | VAF 16/21 reads (76%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV100407086; called by muse, mutect2, varscan2
- OR10H3 | c.326G>T p.G109V | Missense Mutation (SNP) | VAF 63/279 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100008485; called by muse, mutect2, varscan2
- OR10S1 | c.358T>A p.F120I | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as rs759711106, COSV101602492, COSV101602501, COSV73342692; called by muse, mutect2, varscan2
- OR11A1 | c.943G>C p.D315H | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.06); catalogued as rs1480536975, COSV101010730; called by muse, mutect2
- OR11L1 | c.383G>A p.S128N | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV100869476; called by muse, mutect2, varscan2
- OR1I1 | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV99264894; called by muse, mutect2
- OR2AK2 | c.290G>T p.C97F | Missense Mutation (SNP) | VAF 104/284 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100824280; called by muse, mutect2, varscan2
- OR51A7 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.452); catalogued as COSV63788458; called by muse, mutect2, varscan2
- OR51T1 | c.443T>C p.L148P | Missense Mutation (SNP) | VAF 64/174 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100434459; called by muse, mutect2, varscan2
- OR56A1 | c.425A>T p.Q142L | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.13); catalogued as COSV100360530; called by muse, mutect2, varscan2
- OR5L1 | c.340C>A p.L114M | Missense Mutation (SNP) | VAF 48/145 reads (33%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as COSV100450209, COSV61735265; called by muse, mutect2, varscan2
- OR5P2 | c.743A>G p.Y248C | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs946592159, COSV100271431; called by muse, mutect2, varscan2
- OR5T2 | c.860T>A p.V287E | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100507047; called by muse, mutect2, varscan2
- OR8B8 | c.322G>C p.V108L | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.506); catalogued as COSV100045210; called by muse, mutect2, varscan2
- OTOGL | c.2791G>C p.V931L (on ENST00000547103; = p.V922L on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/140 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as COSV101509480; called by muse, mutect2, varscan2
- PAX5 | c.311G>T p.R104L | Missense Mutation (SNP) | VAF 111/198 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as COSV100814532; called by muse, mutect2, varscan2
- PCDH10 | c.591C>A p.H197Q | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV99994317; called by muse, mutect2, varscan2
- PCDH10 | c.592C>G p.R198G | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.414); catalogued as rs775599412, COSV52087165, COSV99994319; called by muse, mutect2, varscan2
- PCDH19 | c.3361G>C p.V1121L (on ENST00000373034 / NM_001184880.2; = p.V1073L on NM_020766.3) | Missense Mutation (SNP) | VAF 61/88 reads (69%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.01); catalogued as COSV55266734, COSV99720594; called by muse, mutect2, varscan2
- PDE3A | c.2649T>G p.Y883* | Nonsense Mutation (SNP) | VAF 75/148 reads (51%) | catalogued as COSV100762693, COSV62973502; called by muse, mutect2, varscan2
- PDZD2 | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs866540413, COSV56873280; called by muse, mutect2, varscan2
- PGM2L1 | c.77A>G p.D26G | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1416498199, COSV99995146; called by muse, mutect2, varscan2
- PIK3C2G | c.1597C>A p.H533N | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV99853551; called by muse, mutect2, varscan2
- PKD1L1 | c.4816T>C p.S1606P | Missense Mutation (SNP) | VAF 48/152 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); catalogued as COSV99221096; called by muse, mutect2, varscan2
- PLA1A | c.522G>T p.M174I | Missense Mutation (SNP) | VAF 56/104 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV56331315, COSV99846027; called by muse, mutect2, varscan2
- PLB1 | c.2884G>T p.G962C | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100579742; called by muse, mutect2, varscan2
- PMS1 | c.1384del p.V462Lfs*14 | Frame Shift Del (DEL) | VAF 26/86 reads (30%) | catalogued as COSV59715730; called by mutect2, pindel, varscan2
- POLR1F | c.620G>T p.R207L | Missense Mutation (SNP) | VAF 51/176 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV99749021; called by muse, mutect2, varscan2
- POTEE | c.2791G>T p.A931S | Missense Mutation (SNP) | VAF 58/309 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.028); catalogued as rs373506597; called by muse, mutect2, varscan2
- PPP1R9A | c.3055C>A p.L1019I | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99197881; called by muse, mutect2, varscan2
- PPP1R9B | c.1859A>G p.D620G | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as COSV100380788; called by muse, mutect2, varscan2
- PPP4R1 | c.2165T>C p.L722P (on ENST00000400556 / NM_001042388.3; = p.L705P on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 165/235 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99553886; called by muse, mutect2, varscan2
- PRDM9 | c.25G>T p.E9* | Nonsense Mutation (SNP) | VAF 29/41 reads (71%) | catalogued as COSV57004951, COSV57010881, COSV99691046; called by muse, mutect2, varscan2
- PRDM9 | c.578A>T p.E193V | Missense Mutation (SNP) | VAF 31/283 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99691052; called by muse, mutect2, varscan2
- PRKAG3 | c.1117G>C p.D373H | Missense Mutation (SNP) | VAF 53/110 reads (48%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.979); catalogued as COSV99292091; called by muse, mutect2, varscan2
- PRSS12 | c.1582G>T p.G528* | Nonsense Mutation (SNP) | VAF 30/114 reads (26%) | catalogued as COSV99628720; called by muse, mutect2, varscan2
- PRTG | c.1811T>C p.V604A | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1445850346, COSV101221473; called by muse, mutect2, varscan2
- PTEN | c.1009T>A p.F337I | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100911069, COSV104426443; called by muse, mutect2, varscan2
- PTPRB | c.4522C>A p.P1508T | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99718671; called by muse, mutect2, varscan2
- PYGL | c.1806G>T p.R602S | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99368994; called by muse, mutect2, varscan2
- PYGO2 | c.805A>G p.T269A | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV63757106; called by muse, mutect2, varscan2
- QPRT | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99569051; called by muse, mutect2, varscan2
- QRFPR | c.703A>T p.S235C | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV100543916; called by muse, mutect2, varscan2
- RADX | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT tolerated (0.06); PolyPhen benign (0.427); catalogued as rs1413989206, COSV100998906; called by muse, mutect2, varscan2
- RAP1GDS1 | c.125G>T p.S42I (on ENST00000408927 / NM_001100427.2; = p.S43I on NM_021159.5) | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.527); catalogued as COSV99217284; called by muse, mutect2, varscan2
- RASD2 | c.202C>A p.Q68K | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV99332898; called by muse, mutect2, varscan2
- RBBP6 | c.3150G>C p.E1050D | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV100154883, COSV60504517; called by muse, mutect2, varscan2
- RBM17 | c.635C>A p.P212Q | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as COSV101159159, COSV65915069; called by muse, mutect2, varscan2
- RECQL5 | c.2161G>A p.A721T | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as rs199621884, COSV58640704; called by muse, varscan2
- RELN | c.163G>T p.V55L | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs753619762, COSV100634596; called by muse, mutect2, varscan2
- RHBDD1 | c.721G>T p.G241* | Nonsense Mutation (SNP) | VAF 16/74 reads (22%) | catalogued as COSV100392118; called by muse, mutect2, varscan2
- RHOQ | c.205G>T p.D69Y | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53189229; called by muse, mutect2, varscan2
- ROBO3 | c.3911C>A p.A1304E | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100127521, COSV100127803; called by muse, varscan2
- RTL9 | c.1541C>A p.P514Q | Missense Mutation (SNP) | VAF 115/168 reads (68%) | SIFT tolerated (0.42); PolyPhen benign (0.153); catalogued as COSV101511773; called by muse, mutect2, varscan2
- SAGE1 | c.922G>T p.D308Y | Missense Mutation (SNP) | VAF 53/80 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0.323); catalogued as COSV61012226; called by muse, mutect2, varscan2
- SBNO2 | c.2483C>T p.P828L | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100684951; called by muse, mutect2
- SBSN | c.227G>T p.G76V | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101510101; called by muse, mutect2, varscan2
- SCG5 | c.256G>T p.G86C | Missense Mutation (SNP) | VAF 35/176 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100276923; called by muse, mutect2, varscan2
- SEMA4A | c.367C>A p.Q123K | Missense Mutation (SNP) | VAF 54/159 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.145); catalogued as COSV100740711; called by muse, mutect2, varscan2
- SERPINA11 | c.1124C>T p.S375L | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV100594145; called by muse, mutect2, varscan2
- SERPINA4 | c.70G>A p.V24I | Missense Mutation (SNP) | VAF 88/116 reads (76%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs769068863, COSV100097423; called by muse, mutect2, varscan2
- SERPIND1 | c.1448G>A p.R483H | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.534); catalogued as rs769878030, COSV99300272; called by muse, mutect2
- SFTPD | c.668-1G>A p.X223_splice | Splice Site (SNP) | VAF 31/59 reads (53%) | catalogued as COSV100954560; called by muse, mutect2, varscan2
- SHARPIN | c.778G>T p.E260* | Nonsense Mutation (SNP) | VAF 12/90 reads (13%) | catalogued as COSV100010566; called by muse, mutect2, varscan2
- SHROOM2 | c.3050G>T p.R1017L | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.038); catalogued as COSV101098986; called by muse, mutect2, varscan2
- SLC17A1 | c.232G>T p.D78Y | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV99766064; called by muse, mutect2, varscan2
- SLC17A2 | c.368G>T p.G123V | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99614866; called by muse, mutect2, varscan2
- SLC26A3 | c.1924C>T p.P642S | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs868146575, COSV60642087; called by muse, mutect2, varscan2
- SLC35F2 | c.376G>A p.V126I | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.771); catalogued as rs758343389, COSV56184839; called by muse, mutect2, varscan2
- SLC39A12 | c.905G>T p.G302V | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.012); catalogued as COSV101070117; called by muse, mutect2, varscan2
- SLCO1B3 | c.2099C>G p.A700G | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV99682100; called by muse, mutect2, varscan2
- SMPDL3A | c.411G>T p.Q137H | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV100868719, COSV100868728; called by muse, mutect2, varscan2
- SNAI1 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771035489, COSV99724009; called by muse, mutect2, varscan2
- SNX2 | c.1512G>T p.L504= | Splice Region (SNP) | VAF 21/30 reads (70%) | catalogued as COSV101075619; called by muse, mutect2, varscan2
- SOGA3 | c.2148C>A p.S716R | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV100847031; called by muse, mutect2, varscan2
- SOX9 | c.159C>A p.F53L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (1); PolyPhen probably damaging (0.982); catalogued as COSV55422580, COSV99818696; called by muse, mutect2, varscan2
- SPACA1 | c.47T>G p.V16G | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.772); catalogued as COSV52760474; called by muse, mutect2
- SPACA1 | c.368G>T p.W123L | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52759242; called by muse, mutect2
- SPAG17 | c.427C>T p.R143* | Nonsense Mutation (SNP) | VAF 31/148 reads (21%) | catalogued as rs370557283; called by muse, mutect2, varscan2
- SPG7 | c.1382C>G p.P461R (on ENST00000268704; = p.P468R on NM_003119.4) | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.96); catalogued as COSV99245356; called by muse, mutect2, varscan2
- SPHKAP | c.3454G>T p.A1152S | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100764469; called by muse, mutect2, varscan2
- SPIC | c.139G>T p.V47F | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.154); catalogued as COSV100163042; called by muse, mutect2, varscan2
- SPIRE2 | c.1652C>G p.A551G | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100988732, COSV100988957; called by muse, mutect2, varscan2
- STK31 | c.2558G>T p.G853V | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100669846, COSV63455085; called by muse, mutect2, varscan2
- SUGCT | c.1036G>T p.G346* | Nonsense Mutation (SNP) | VAF 6/28 reads (21%) | catalogued as COSV100004012; called by muse, mutect2
- SUGCT | c.1037G>T p.G346V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV100004014; called by muse, mutect2, varscan2
- SYNE1 | c.5686A>T p.S1896C (on ENST00000367255 / NM_182961.4; = p.S1903C on NM_033071.3) | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as COSV99575542; called by muse, mutect2, varscan2
- TAX1BP1 | c.751G>T p.E251* | Nonsense Mutation (SNP) | VAF 15/54 reads (28%) | catalogued as COSV55292610, COSV99604705; called by muse, mutect2, varscan2
- TBC1D2B | c.709G>T p.G237W | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs78493089, COSV100317634; called by muse, mutect2, varscan2
- TCF7L2 | c.1144C>A p.Q382K (on ENST00000355995 / NM_001367943.1; = p.Q359K on NM_030756.5) | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV99526572; called by muse, mutect2, varscan2
- TFPI | c.372C>A p.F124L | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as COSV51899362, COSV51905712; called by muse, mutect2, varscan2
- THOP1 | c.898C>T p.Q300* | Nonsense Mutation (SNP) | VAF 9/28 reads (32%) | catalogued as COSV100310750; called by muse, mutect2, varscan2
- THSD7B | c.242G>T p.C81F | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99756987; called by muse, mutect2, varscan2
- TIAM1 | c.2531A>G p.Q844R | Missense Mutation (SNP) | VAF 23/36 reads (64%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV54559676, COSV99738194; called by muse, mutect2, varscan2
- TLL1 | c.973G>T p.A325S | Missense Mutation (SNP) | VAF 55/152 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as COSV50266242; called by muse, mutect2, varscan2
- TM4SF20 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV100460175; called by muse, mutect2, varscan2
- TMBIM6 | c.286G>C p.G96R | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99920825; called by muse, mutect2, varscan2
- TMEM156 | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1275236510, COSV100756090; called by muse, mutect2, varscan2
- TNFSF9 | c.692G>A p.G231D | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.18); PolyPhen benign (0.204); catalogued as rs1568421049, COSV99832443; called by muse, mutect2, varscan2
- TNIP3 | c.899G>T p.W300L | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV99284437; called by muse, mutect2, varscan2
- TNR | c.991G>A p.D331N | Missense Mutation (SNP) | VAF 54/154 reads (35%) | SIFT tolerated (0.7); PolyPhen benign (0.015); catalogued as COSV99691099; called by muse, mutect2, varscan2
- TOGARAM1 | c.100G>T p.D34Y | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100753254; called by muse, mutect2, varscan2
- TRPC3 | c.718G>T p.A240S (on ENST00000379645 / NM_001366479.2; = p.A167S on NM_003305.2) | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369264817; called by muse, varscan2
- TRPM6 | c.4385A>C p.E1462A | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.197); catalogued as COSV100666855; called by muse, mutect2, varscan2
- TTLL7 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs267598737, COSV53088658; called by muse, mutect2
- TTN | c.94720C>T p.R31574W (on ENST00000591111; = p.R24150W on NM_003319.4) | Missense Mutation (SNP) | VAF 25/60 reads (42%) | PolyPhen probably damaging (0.999); catalogued as rs377598016, COSV59899873; called by muse, mutect2, varscan2
- TTN | c.85385T>C p.V28462A (on ENST00000591111; = p.V21038A on NM_003319.4) | Missense Mutation (SNP) | VAF 26/66 reads (39%) | PolyPhen possibly damaging (0.894); catalogued as COSV100626178; called by muse, mutect2, varscan2
- TTN | c.34753C>G p.P11585A (on ENST00000591111; = p.P10658A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/139 reads (31%) | PolyPhen benign (0.025); catalogued as COSV100626180; called by muse, mutect2, varscan2
- TTN | c.1205C>A p.A402D | Missense Mutation (SNP) | VAF 29/105 reads (28%) | PolyPhen benign (0.069); catalogued as COSV60165976; called by muse, mutect2, varscan2
- TXNDC11 | c.2146G>T p.A716S (on ENST00000356957 / NM_001303447.2; = p.A689S on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.234); catalogued as rs767698991, COSV51602725, COSV99298272; called by muse, mutect2, varscan2
- UBASH3B | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 56/204 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs1471355844, COSV99418629; called by muse, mutect2, varscan2
- UGT2B11 | c.1089A>T p.L363= | Splice Region (SNP) | VAF 32/105 reads (30%) | catalogued as COSV101485286; called by muse, mutect2, varscan2
- UNC13C | c.3089A>G p.Y1030C | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV99521993; called by muse, mutect2, varscan2
- URB2 | c.3274G>T p.V1092L | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99271758; called by muse, mutect2, varscan2
- USH2A | c.689T>C p.V230A | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.138); catalogued as rs1373126699, COSV100240834; called by muse, mutect2, varscan2
- USP20 | c.2305G>A p.G769R | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs1002106217, COSV100204682; called by muse, mutect2, varscan2
- UTP23 | c.679A>G p.K227E | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.257); catalogued as COSV100561262; called by muse, mutect2, varscan2
- VASP | c.1090G>C p.E364Q | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs145748539, COSV99841125; called by muse, mutect2, varscan2
- VEPH1 | c.949G>A p.A317T | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as COSV100747925; called by muse, mutect2, varscan2
- VILL | c.1746G>T p.Q582H | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV99379189; called by muse, mutect2, varscan2
- VIP | c.478G>C p.E160Q | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.122); catalogued as COSV100923962, COSV65889022; called by muse, mutect2, varscan2
- WDR35 | c.3400G>A p.E1134K (on ENST00000345530 / NM_001006657.2; = p.E1123K on NM_020779.4) | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs774573858, COSV99853461; called by muse, mutect2, varscan2
- WDR62 | c.788G>C p.G263A | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54336669; called by muse, mutect2, varscan2
- WNK2 | c.1050A>T p.R350S | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99944169; called by muse, mutect2, varscan2
- ZAN | c.5330G>C p.G1777A | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100770186; called by muse, mutect2, varscan2
- ZBTB21 | c.1322C>T p.S441L | Missense Mutation (SNP) | VAF 44/71 reads (62%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs758033755, COSV60403276; called by muse, mutect2, varscan2
- ZBTB41 | c.669G>T p.E223D | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as COSV100963394; called by muse, mutect2
- ZDBF2 | c.1537G>A p.V513I | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.083); catalogued as COSV100985406; called by muse, mutect2, varscan2
- ZFP36L1 | c.416A>T p.H139L | Missense Mutation (SNP) | VAF 152/216 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100322845; called by muse, mutect2, varscan2
- ZFYVE26 | c.7270C>A p.Q2424K | Missense Mutation (SNP) | VAF 21/25 reads (84%) | SIFT deleterious (0.01); PolyPhen benign (0.234); catalogued as COSV100720686; called by muse, mutect2, varscan2
- ZNF266 | c.284C>T p.T95I | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV100749436; called by muse, mutect2, varscan2
- ZNF479 | c.712G>T p.E238* | Nonsense Mutation (SNP) | VAF 19/49 reads (39%) | catalogued as COSV100482996; called by muse, mutect2, varscan2
- ZNF502 | c.968A>G p.H323R | Missense Mutation (SNP) | VAF 81/137 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV99939839; called by muse, mutect2, varscan2
- ZNF581 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1417390736, COSV54402470; called by muse, mutect2, varscan2
- ZNF618 | c.582del p.K195Rfs*44 (on ENST00000374126 / NM_001318042.2; = p.K163Rfs*44 on NM_133374.2) | Frame Shift Del (DEL) | VAF 13/33 reads (39%) | catalogued as COSV99930296; called by mutect2, pindel, varscan2
- ZNF676 | c.1474T>C p.W492R (on ENST00000650058; = p.W460R on NM_001001411.3) | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0.011); catalogued as COSV101236310; called by muse, mutect2, varscan2
- ZNF700 | c.1679G>C p.G560A | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as COSV99583746; called by muse, mutect2, varscan2
- ZNF75A | c.452A>C p.H151P | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); catalogued as COSV101556636; called by muse, mutect2, varscan2
- ABCB9 | c.1011dup p.I338Hfs*47 | Frame Shift Ins (INS) | VAF 7/31 reads (23%) | called by mutect2, pindel, varscan2
- ANAPC1 | c.3193G>A p.E1065K | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- CRYGA | c.506G>T p.R169L | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); called by muse, mutect2, varscan2
- DNAH5 | c.4512del p.H1505Tfs*12 | Frame Shift Del (DEL) | VAF 70/90 reads (78%) | called by mutect2, pindel*, varscan2
- FOXD4L3 | c.607C>A p.R203S | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- IGHV3-11 | c.170G>T p.R57L | Missense Mutation (SNP) | VAF 248/332 reads (75%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- IGKV2-28 | c.91C>A p.L31M | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- SLC24A5 | c.12del p.G6Afs*65 | Frame Shift Del (DEL) | VAF 6/31 reads (19%) | called by mutect2, varscan2
- SPACA1 | c.368-1G>C p.X123_splice | Splice Site (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
- SRCIN1 | c.3367C>A p.L1123I (on ENST00000621492; = p.L1089I on NM_025248.3) | Missense Mutation (SNP) | VAF 46/88 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); called by muse, mutect2
- TPTE | c.1363del p.D455Ifs*9 (on ENST00000618007 / NM_199261.4; = p.D437Ifs*9 on NM_199259.4) | Frame Shift Del (DEL) | VAF 26/160 reads (16%) | called by mutect2, pindel, varscan2
- TRAV14DV4 | c.310C>A p.L104M | Missense Mutation (SNP) | VAF 56/133 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- TRAV14DV4 | c.311T>A p.L104Q | Missense Mutation (SNP) | VAF 56/133 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- TRAV9-1 | c.61G>T p.D21Y | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- ZNF292 | c.6058C>A p.Q2020K | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2
- ABCC8 | c.1777C>T p.L593= | Silent (SNP) | VAF 150/270 reads (56%) | catalogued as COSV100217627; called by muse, mutect2, varscan2
- AC011455.2 | c.909G>T p.G303= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as COSV99671513; called by muse, mutect2, varscan2
- ACP2 | c.1215G>A p.R405= | Silent (SNP) | VAF 31/103 reads (30%) | catalogued as COSV99921819; called by muse, mutect2, varscan2
- ADAMTS10 | c.2343G>T p.G781= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as rs782209958, COSV99547336; called by muse, mutect2, varscan2
- ADAMTS16 | c.1752C>G p.P584= | Silent (SNP) | VAF 14/156 reads (9%) | catalogued as COSV56995772, COSV99942558; called by muse, mutect2
- ADAMTS20 | c.363A>G p.A121= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV101240140; called by mutect2, varscan2
- ADCY10 | c.2982G>A p.K994= | Silent (SNP) | VAF 25/60 reads (42%) | catalogued as COSV100897031, COSV63238898; called by muse, mutect2, varscan2
- ADGRF3 | c.441C>A p.L147= (on ENST00000311519 / NM_001145168.1; = p.L88= on NM_153835.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as COSV100275326; called by muse, mutect2, varscan2
- AHI1 | c.2565G>C p.G855= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV99663522; called by muse, varscan2
- AL592490.1 | c.657G>A p.P219= | Silent (SNP) | VAF 31/113 reads (27%) | catalogued as COSV101308186; called by muse, mutect2, varscan2
- ANK2 | c.5227T>C p.L1743= | Silent (SNP) | VAF 105/370 reads (28%) | catalogued as COSV100003652; called by muse, mutect2, varscan2
- AP3D1 | c.1770G>T p.V590= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV100642981; called by muse, mutect2, varscan2
- APBA2 | c.1827G>A p.S609= | Silent (SNP) | VAF 18/85 reads (21%) | catalogued as rs376883824, COSV67105408; ClinVar: likely benign; called by muse, mutect2, varscan2
- ARHGAP6 | c.2745C>T p.A915= (on ENST00000337414 / NM_013427.3; = p.A712= on NM_013423.3) | Silent (SNP) | VAF 8/10 reads (80%) | catalogued as rs1211815824, COSV100273488; called by muse, mutect2, varscan2
- ARRDC1 | c.1179G>T p.V393= | Silent (SNP) | VAF 19/117 reads (16%) | catalogued as COSV100604159; called by muse, mutect2, varscan2
- ATG9A | c.1965C>T p.F655= | Silent (SNP) | VAF 28/105 reads (27%) | catalogued as COSV99522151; called by muse, mutect2, varscan2
- ATOH1 | c.984C>T p.S328= | Silent (SNP) | VAF 40/141 reads (28%) | catalogued as COSV100024561; called by muse, mutect2, varscan2
- BAIAP3 | c.768C>T p.A256= | Silent (SNP) | VAF 35/83 reads (42%) | catalogued as COSV100181840; called by muse, mutect2, varscan2
- BMPER | c.1224C>T p.D408= | Silent (SNP) | VAF 18/222 reads (8%) | catalogued as rs376960971, COSV51814145; called by muse, mutect2
- CACNA1I | c.4488C>A p.I1496= | Silent (SNP) | VAF 69/182 reads (38%) | catalogued as rs772387631, COSV100361283; called by muse, mutect2, varscan2
- CDH18 | c.330C>A p.I110= | Silent (SNP) | VAF 113/147 reads (77%) | catalogued as COSV99937599; called by muse, mutect2, varscan2
- CEP250 | c.4227C>A p.G1409= | Silent (SNP) | VAF 23/64 reads (36%) | catalogued as COSV100699127; called by muse, mutect2, varscan2
- COL15A1 | c.1017T>C p.T339= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as rs1004082080, COSV100897925; called by muse, mutect2, varscan2
- COL22A1 | c.4839C>T p.F1613= | Silent (SNP) | VAF 33/54 reads (61%) | catalogued as rs777805657, COSV57330681; called by muse, mutect2, varscan2
- CPD | c.549C>T p.N183= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs1267635898, COSV99853203; called by muse, mutect2
- DDX25 | c.558G>T p.V186= | Silent (SNP) | VAF 31/83 reads (37%) | catalogued as COSV99700086; called by muse, mutect2, varscan2
- DMD | c.5749C>A p.R1917= | Silent (SNP) | VAF 10/15 reads (67%) | catalogued as rs763893272, COSV63741502; called by muse, mutect2, varscan2
- DOT1L | c.3063C>T p.P1021= | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as rs374450517; called by muse, mutect2, varscan2
- DTNB | c.651T>G p.P217= | Silent (SNP) | VAF 34/80 reads (43%) | catalogued as COSV99977908; called by muse, mutect2, varscan2
- DTNBP1 | c.282C>T p.L94= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as rs753298238, COSV59038102; called by muse, mutect2, varscan2
- E2F6 | c.501G>A p.Q167= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV100215391; called by muse, mutect2, varscan2
- EGFL8 | c.117C>G p.S39= | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as COSV100247068, COSV61247009; called by muse, mutect2, varscan2
- EMILIN2 | c.1800C>A p.T600= | Silent (SNP) | VAF 32/41 reads (78%) | catalogued as COSV99598825; called by muse, mutect2, varscan2
- ERBB3 | c.2574G>T p.L858= | Silent (SNP) | VAF 37/131 reads (28%) | catalogued as COSV99917650; called by muse, mutect2, varscan2
- ERGIC2 | c.339A>G p.V113= | Silent (SNP) | VAF 33/111 reads (30%) | catalogued as COSV100792025; called by muse, mutect2, varscan2
- ESPL1 | c.5157A>T p.G1719= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV99229681; called by muse, mutect2, varscan2
- F13B | c.1429T>C p.L477= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV100803404, COSV66372161; called by muse, mutect2, varscan2
- FAAP100 | c.1755C>G p.G585= | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as COSV100585563; called by muse, mutect2, varscan2
- FAM135B | c.996C>A p.T332= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as COSV99426702; called by muse, mutect2, varscan2
- FAM47C | c.54G>A p.T18= | Silent (SNP) | VAF 16/18 reads (89%) | catalogued as COSV100792914, COSV63723442; called by muse, mutect2, varscan2
- FAT3 | c.12180G>A p.E4060= | Silent (SNP) | VAF 49/151 reads (32%) | catalogued as rs771673019, COSV99969889; called by muse, mutect2, varscan2
- FBXO15 | c.1311C>A p.P437= | Silent (SNP) | VAF 19/214 reads (9%) | catalogued as COSV99503700; called by muse, mutect2
- FGF21 | c.513C>A p.P171= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV99711541; called by muse, mutect2, varscan2
- FHOD1 | c.2244G>A p.K748= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV99264436; called by muse, mutect2, varscan2
- FMNL2 | c.423A>C p.S141= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs766221413, COSV99980495; called by muse, mutect2, varscan2
- FOXA2 | c.1224G>T p.V408= (on ENST00000377115 / NM_153675.3; = p.V414= on NM_021784.5) | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as COSV101008453; called by muse, mutect2, varscan2
- FOXD4L6 | c.1137G>T p.L379= | Silent (SNP) | VAF 12/56 reads (21%) | called by mutect2, varscan2
- GABRB3 | c.975C>A p.A325= | Silent (SNP) | VAF 32/120 reads (27%) | catalogued as COSV100161377; called by muse, mutect2, varscan2
- GGT1 | c.1191C>T p.T397= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs1407712471, COSV99959249; called by muse, mutect2, varscan2
- GRN | c.468C>A p.S156= | Silent (SNP) | VAF 41/173 reads (24%) | catalogued as CD075438, COSV99275061; called by muse, mutect2, varscan2
- HOXA6 | c.508C>T p.L170= | Silent (SNP) | VAF 88/225 reads (39%) | catalogued as COSV99762457; called by muse, mutect2, varscan2
- HTR1D | c.327C>T p.I109= | Silent (SNP) | VAF 25/91 reads (27%) | catalogued as rs1454906409, COSV100025029; called by muse, mutect2, varscan2
- HYDIN | c.7674G>T p.G2558= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV59260714, COSV99993529; called by muse, mutect2
- IL15 | c.291T>A p.V97= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as COSV99650789; called by muse, mutect2, varscan2
- ITGAX | c.567C>T p.S189= | Silent (SNP) | VAF 46/103 reads (45%) | catalogued as rs1437160488, COSV99191981; called by muse, mutect2, varscan2
- ITIH5 | c.2781A>T p.P927= | Silent (SNP) | VAF 84/198 reads (42%) | catalogued as COSV99905529; called by muse, mutect2, varscan2
- ITPKB | c.2322C>A p.I774= | Silent (SNP) | VAF 93/259 reads (36%) | catalogued as rs750503076, COSV55263096, COSV99684488, COSV99685002; called by muse, mutect2, varscan2
- KBTBD7 | c.357C>T p.A119= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as rs1205126215, COSV101068187; called by muse, mutect2, varscan2
- KCNH1 | c.930C>T p.N310= | Silent (SNP) | VAF 28/146 reads (19%) | catalogued as rs776240703, COSV55089116; called by muse, mutect2, varscan2
- KCNH6 | c.900C>A p.L300= | Silent (SNP) | VAF 70/152 reads (46%) | catalogued as COSV100121218; called by muse, mutect2, varscan2
- KCNV1 | c.960G>T p.L320= | Silent (SNP) | VAF 21/50 reads (42%) | catalogued as rs1257336369, COSV99819371; called by muse, mutect2, varscan2
- KDM2B | c.1314G>T p.P438= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV100997622; called by muse, mutect2, varscan2
- KIF26B | c.5235G>A p.A1745= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as rs747644735, COSV100833223; called by muse, mutect2, varscan2
- KLHL4 | c.774A>T p.A258= | Silent (SNP) | VAF 22/40 reads (55%) | catalogued as COSV100910101; called by muse, mutect2, varscan2
- KMT2D | c.13173G>A p.Q4391= | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as COSV56484034, COSV99985175; called by muse, mutect2, varscan2
- LIG4 | c.2106A>T p.A702= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as COSV100800044; called by muse, mutect2, varscan2
- LIPG | c.663C>A p.T221= | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as COSV54298812; called by muse, mutect2, varscan2
- LNX2 | c.1566C>A p.I522= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV100310877; called by muse, mutect2, varscan2
- LRRC7 | c.1974C>A p.A658= (on ENST00000651989 / NM_001370785.2; = p.A625= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 26/38 reads (68%) | catalogued as COSV99229150; called by muse, mutect2, varscan2
- LRRC73 | c.288C>A p.P96= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV99447373; called by muse, mutect2, varscan2
- MAG | c.1809G>A p.G603= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as COSV100728019; called by muse, mutect2, varscan2
- MDGA2 | c.1758C>T p.T586= (on ENST00000399232 / NM_001113498.2; = p.T288= on NM_182830.4) | Silent (SNP) | VAF 55/156 reads (35%) | catalogued as rs1566585006, COSV100638106, COSV100638364; called by muse, mutect2, varscan2
- MINAR1 | c.1743G>T p.R581= | Silent (SNP) | VAF 12/85 reads (14%) | catalogued as COSV100549160, COSV100549370; called by muse, mutect2, varscan2
- MMP26 | c.714C>T p.F238= | Silent (SNP) | VAF 25/66 reads (38%) | catalogued as COSV100332235; called by muse, mutect2, varscan2
- MYO1B | c.1287G>C p.R429= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV100269838; called by muse, mutect2, varscan2
- MYO1D | c.1443A>G p.K481= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as COSV100554817; called by muse, mutect2, varscan2
- NEO1 | c.4365A>G p.L1455= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV99982666; called by muse, mutect2, varscan2
- NME8 | c.1657C>A p.R553= | Silent (SNP) | VAF 27/104 reads (26%) | catalogued as COSV52250845, COSV52253458; called by muse, mutect2, varscan2
- NOS1 | c.3144C>T p.L1048= | Silent (SNP) | VAF 27/53 reads (51%) | catalogued as rs374883833; called by muse, mutect2, varscan2
- NPAS2 | c.1488G>T p.S496= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as rs749773234, COSV100176794; called by muse, mutect2, varscan2
- NT5C1B-RDH14 | c.1794A>G p.L598= (on ENST00000532967 / NM_001199104.1; = p.R449G on NM_001199103.1) | Silent (SNP) | VAF 30/123 reads (24%) | catalogued as COSV101173361; called by muse, mutect2, varscan2
- NYNRIN | c.2352A>T p.S784= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as COSV101230635; called by muse, mutect2, varscan2
- OR10G8 | c.618C>G p.A206= | Silent (SNP) | VAF 36/84 reads (43%) | catalogued as COSV101461869; called by muse, mutect2, varscan2
- OR7D4 | c.48A>G p.G16= | Silent (SNP) | VAF 47/95 reads (49%) | catalogued as COSV100432848; called by muse, mutect2, varscan2
- PAPPA2 | c.1554C>T p.P518= | Silent (SNP) | VAF 31/79 reads (39%) | catalogued as rs553799926, COSV100866963; called by muse, mutect2, varscan2
- PLGRKT | c.369G>T p.L123= | Silent (SNP) | VAF 24/41 reads (59%) | catalogued as COSV99803991; called by muse, mutect2, varscan2
- POU6F1 | c.1404G>C p.R468= | Silent (SNP) | VAF 31/148 reads (21%) | catalogued as COSV100374881; called by muse, mutect2, varscan2
- PTGS1 | c.165G>A p.Q55= | Silent (SNP) | VAF 32/87 reads (37%) | catalogued as COSV99793447; called by muse, mutect2, varscan2
- REG1A | c.207G>C p.S69= | Silent (SNP) | VAF 15/101 reads (15%) | catalogued as COSV52069019, COSV99286952; called by muse, mutect2, varscan2
- RYR1 | c.11535C>T p.A3845= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV100616720; called by muse, mutect2, varscan2
- SAP130 | c.915G>T p.T305= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV99385209; called by muse, mutect2, varscan2
- SHANK1 | c.6429C>A p.T2143= | Silent (SNP) | VAF 34/74 reads (46%) | catalogued as COSV53262295; called by muse, mutect2, varscan2
- SLC9B2 | c.1269C>T p.A423= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs1294877477, COSV100294257; called by muse, mutect2, varscan2
- SMARCC2 | c.3333C>T p.P1111= | Silent (SNP) | VAF 42/77 reads (55%) | catalogued as rs757457608, COSV53238866; called by muse, mutect2, varscan2
- SUN5 | c.441G>A p.K147= | Silent (SNP) | VAF 88/226 reads (39%) | catalogued as COSV100644891; called by muse, mutect2, varscan2
- SYNE1 | c.10572T>C p.D3524= (on ENST00000367255 / NM_182961.4; = p.D3531= on NM_033071.3) | Silent (SNP) | VAF 45/121 reads (37%) | catalogued as COSV99575539; called by muse, mutect2, varscan2
- TBC1D4 | c.3276T>C p.F1092= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as COSV100884759; called by muse, mutect2, varscan2
- TECPR1 | c.906G>T p.V302= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as COSV101130701; called by muse, mutect2, varscan2
- TMEM44 | c.981C>A p.A327= (on ENST00000392432 / NM_001166305.2; = p.A280= on NM_138399.5) | Silent (SNP) | VAF 9/219 reads (4%) | catalogued as COSV99861961; called by muse, mutect2
- TNR | c.192C>G p.V64= | Silent (SNP) | VAF 71/162 reads (44%) | catalogued as COSV99691100; called by muse, mutect2, varscan2
- TRIML1 | c.901T>C p.L301= | Silent (SNP) | VAF 42/98 reads (43%) | catalogued as COSV100206254; called by muse, mutect2, varscan2
- TRPC3 | c.771C>A p.A257= (on ENST00000379645 / NM_001366479.2; = p.A184= on NM_003305.2) | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV99313364; called by muse, varscan2
- TRRAP | c.9978C>A p.V3326= (on ENST00000359863 / NM_001244580.1; = p.V3297= on NM_003496.3) | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as COSV100722821; called by muse, mutect2, varscan2
- TTN | c.759A>T p.T253= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as COSV100626181; called by muse, mutect2, varscan2
- TUT4 | c.4170G>T p.L1390= | Silent (SNP) | VAF 21/28 reads (75%) | catalogued as COSV99932732; called by muse, mutect2, varscan2
- ZFHX3 | c.1629G>T p.L543= | Silent (SNP) | VAF 48/98 reads (49%) | catalogued as COSV99214304; called by muse, mutect2, varscan2
- ZNF202 | c.915G>A p.E305= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs1297974321, COSV60246330; called by muse, mutect2, varscan2
- ZNF385C | c.1149A>G p.S383= | Silent (SNP) | VAF 29/68 reads (43%) | catalogued as COSV100288870; called by muse, mutect2, varscan2
- ZNF536 | c.792G>A p.Q264= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV100835707; called by muse, mutect2, varscan2
- ZNF804B | c.1407C>A p.P469= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as COSV100305604; called by muse, mutect2, varscan2
- AP1S3 | c.430-5834A>T | Intron (SNP) | VAF 7/15 reads (47%) | catalogued as COSV100525395; called by muse, mutect2, varscan2
- BIRC8 | n.1265A>T | RNA (SNP) | VAF 50/108 reads (46%) | catalogued as COSV101461358; called by muse, mutect2, varscan2
- CCNQP1 | n.526G>A | RNA (SNP) | VAF 39/94 reads (41%) | catalogued as rs766572375; called by muse, mutect2, varscan2
- CTBP2 | c.59-2063C>T | Intron (SNP) | VAF 5/16 reads (31%) | catalogued as rs750984584, COSV100456831; called by muse, mutect2, varscan2
- DIABLO | c.-37+1365A>G | Intron (SNP) | VAF 60/108 reads (56%) | catalogued as COSV99928338; called by muse, mutect2, varscan2
- DPP6 | c.*199G>T | 3'UTR (SNP) | VAF 8/35 reads (23%) | catalogued as COSV100127582; called by muse, mutect2, varscan2
- HERC2P3 | n.1622G>A | RNA (SNP) | VAF 6/42 reads (14%) | called by mutect2, varscan2
- KLC4 | c.-21G>T | 5'UTR (SNP) | VAF 22/63 reads (35%) | catalogued as COSV99432480; called by muse, mutect2, varscan2
- RORA | c.196+51350G>C | Intron (SNP) | VAF 55/114 reads (48%) | catalogued as COSV99833009; called by muse, mutect2, varscan2
